Somatic mutation profile of cancer-model specimen HCM-BROD-0101-C15-85A (3D Organoid, passage 6; aliquot HCM-BROD-0101-C15-85A-01D-A79L-36), derived from the metastatic tumor of HCMI case HCM-BROD-0101-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 64.0 years (23,385 days).
Specimen HCM-BROD-0101-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d3eca14d-d72c-4e41-8fca-9afedb30b94e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0101-C15-10B (Blood Derived Normal), aliquot HCM-BROD-0101-C15-10B-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2bea81f2-7c19-43c5-a2e7-fb88c484f4d1

The open-access MAF lists 652 somatic variants for this specimen: 498 protein-altering or splice-affecting, 130 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 465, Silent 130, Nonsense Mutation 19, Intron 12, Splice Region 6, 3'UTR 4, 3'Flank 3, 5'Flank 3, Frame Shift Ins 2, Nonstop Mutation 2, Frame Shift Del 2, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A1BG | c.220T>C p.S74P | Missense Mutation (SNP) | VAF 251/543 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.378); catalogued as rs1242614849; called by muse, mutect2, varscan2
- ACADM | c.1085G>C p.G362A | Missense Mutation (SNP) | VAF 189/529 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as CM090225; called by muse, mutect2, varscan2
- ACOX1 | c.1214G>A p.S405N | Missense Mutation (SNP) | VAF 221/221 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as COSV99503799; called by muse, mutect2, varscan2
- ALKBH1 | c.1000T>G p.L334V | Missense Mutation (SNP) | VAF 210/424 reads (50%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.832); catalogued as COSV53659884; called by muse, mutect2, varscan2
- ANK3 | c.2879T>G p.L960R (on ENST00000280772 / NM_001320874.2; = p.L94R on NM_001149.3) | Missense Mutation (SNP) | VAF 92/384 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV55073120; called by muse, mutect2, varscan2
- ATCAY | c.436G>A p.G146S | Missense Mutation (SNP) | VAF 308/667 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.073); catalogued as rs570425021; called by muse, mutect2, varscan2
- ATP8B3 | c.1838G>A p.R613H | Missense Mutation (SNP) | VAF 212/508 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774346791; called by muse, mutect2
- B4GALT7 | c.790C>T p.R264W | Missense Mutation (SNP) | VAF 256/515 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs779147014; ClinVar: uncertain significance; called by muse, varscan2
- BMP5 | c.887C>G p.S296* | Nonsense Mutation (SNP) | VAF 625/1214 reads (51%) | catalogued as COSV100895961; called by muse, mutect2, varscan2
- BPIFB1 | c.1190T>C p.L397P | Missense Mutation (SNP) | VAF 114/470 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1028339651; called by muse, mutect2, varscan2
- BRCA1 | c.1253A>C p.E418A | Missense Mutation (SNP) | VAF 143/299 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.812); catalogued as rs1555592050; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- BRD8 | c.34A>G p.S12G | Missense Mutation (SNP) | VAF 99/215 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.297); catalogued as rs748880737; called by muse, mutect2, varscan2
- CABIN1 | c.4714T>C p.F1572L | Missense Mutation (SNP) | VAF 123/387 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.952); catalogued as rs1427585085; called by muse, mutect2, varscan2
- CCT8L2 | c.337G>T p.E113* | Nonsense Mutation (SNP) | VAF 198/656 reads (30%) | catalogued as COSV63462373; called by muse, mutect2, varscan2
- CD300LB | c.365A>T p.D122V | Missense Mutation (SNP) | VAF 88/160 reads (55%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.801); catalogued as COSV58725536; called by muse, varscan2
- CDR2 | c.523C>T p.H175Y | Missense Mutation (SNP) | VAF 81/353 reads (23%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.937); catalogued as COSV99193465; called by muse, mutect2, varscan2
- CEACAM7 | c.389T>G p.L130R | Missense Mutation (SNP) | VAF 166/367 reads (45%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.94); catalogued as rs1555811250; called by muse, mutect2
- CENPF | c.8283A>C p.K2761N | Missense Mutation (SNP) | VAF 78/305 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.597); catalogued as COSV100871478; called by muse, mutect2, varscan2
- CFAP100 | c.995C>T p.T332M | Missense Mutation (SNP) | VAF 199/646 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs111705111; called by muse, mutect2, varscan2
- CGN | c.2312A>G p.E771G | Missense Mutation (SNP) | VAF 99/332 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1008824295, COSV54968067; called by muse, mutect2, varscan2
- CHAT | c.1259G>A p.R420H | Missense Mutation (SNP) | VAF 332/332 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1282757667, COSV60326083; called by muse, mutect2, varscan2
- CIP2A | c.2536T>G p.L846V | Missense Mutation (SNP) | VAF 65/258 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.305); catalogued as rs1337419518; called by muse, mutect2, varscan2
- CPN1 | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 332/332 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs767121462, COSV64942738; called by muse, mutect2, varscan2
- CR1 | c.3106C>T p.R1036* | Nonsense Mutation (SNP) | VAF 340/475 reads (72%) | catalogued as rs771592989; called by muse, mutect2, varscan2
- CSMD3 | c.7240G>C p.E2414Q (on ENST00000297405 / NM_001363185.1; = p.E2310Q on NM_052900.3) | Missense Mutation (SNP) | VAF 116/288 reads (40%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.531); catalogued as COSV52182105; called by muse, mutect2, varscan2
- DCBLD1 | c.679C>T p.R227* | Nonsense Mutation (SNP) | VAF 327/327 reads (100%) | catalogued as rs754059942, COSV51639826; called by muse, mutect2, varscan2
- DNAI3 | c.2311T>G p.F771V | Missense Mutation (SNP) | VAF 92/312 reads (29%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs750935204; called by muse, mutect2, varscan2
- DOCK5 | c.1722T>C p.G574= | Splice Region (SNP) | VAF 90/91 reads (99%) | catalogued as rs1296852166; called by muse, mutect2, varscan2
- EHF | c.587A>C p.K196T | Missense Mutation (SNP) | VAF 147/529 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.115); catalogued as rs893559202; called by muse, mutect2, varscan2
- EP300 | c.4382A>C p.K1461T | Missense Mutation (SNP) | VAF 146/428 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54332290; called by muse, mutect2, varscan2
- ETV6 | c.1193T>G p.L398R | Missense Mutation (SNP) | VAF 240/242 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1511685, COSV56766205; called by muse, mutect2, varscan2
- FAT3 | c.8239C>T p.R2747W | Missense Mutation (SNP) | VAF 163/332 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as rs200763217; called by muse, mutect2, varscan2
- FBXW8 | c.363G>A p.A121= (on ENST00000309909; = p.A159= on NM_012174.1) | Splice Region (SNP) | VAF 125/274 reads (46%) | catalogued as rs1158700124; called by muse, mutect2, varscan2
- FER1L5 | c.3025G>A p.A1009T (on ENST00000623019; = p.A1016T on NM_001293083.2) | Missense Mutation (SNP) | VAF 324/602 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as rs939522468, COSV67606006; called by muse, varscan2
- GANAB | c.863A>C p.E288A | Missense Mutation (SNP) | VAF 188/369 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as COSV60462512; called by muse, mutect2, varscan2
- GFUS | c.810C>T p.T270= | Splice Region (SNP) | VAF 195/627 reads (31%) | catalogued as rs773696464; called by muse, mutect2, varscan2
- GLYATL2 | c.641G>C p.W214S | Missense Mutation (SNP) | VAF 143/342 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99780181; called by muse, mutect2, varscan2
- GMEB2 | c.1235A>G p.K412R | Missense Mutation (SNP) | VAF 305/1176 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.093); catalogued as rs1244315351; called by muse, mutect2, varscan2
- GRIK2 | c.1801G>A p.V601M | Missense Mutation (SNP) | VAF 23/424 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.327); catalogued as COSV59732401; called by muse, mutect2
- H3-5 | c.208T>A p.L70M | Missense Mutation (SNP) | VAF 542/546 reads (99%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs777292400; called by muse, mutect2, varscan2
- HCRTR2 | c.403A>G p.T135A | Missense Mutation (SNP) | VAF 193/700 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.085); catalogued as rs1023907475; called by muse, mutect2, varscan2
- IGKV3-15 | c.157T>G p.L53V | Missense Mutation (SNP) | VAF 117/569 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.076); catalogued as rs768194531; called by muse, mutect2, varscan2
- IPMK | c.718T>C p.F240L | Missense Mutation (SNP) | VAF 101/452 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100880282; called by muse, mutect2, varscan2
- IRF6 | c.1166T>C p.L389P | Missense Mutation (SNP) | VAF 76/288 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65419158; called by muse, varscan2
- KCNB1 | c.1748G>C p.R583P | Missense Mutation (SNP) | VAF 331/682 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.223); catalogued as COSV100870504; called by muse, mutect2, varscan2
- KHDRBS2 | c.911A>G p.D304G | Missense Mutation (SNP) | VAF 142/725 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as COSV55474260; called by muse, mutect2
- KMT5B | c.1856T>C p.L619P | Missense Mutation (SNP) | VAF 213/629 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs772536209; called by muse, mutect2, varscan2
- KRT75 | c.662T>C p.L221P | Missense Mutation (SNP) | VAF 161/316 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99359522; called by muse, mutect2, varscan2
- LAMB4 | c.3935A>G p.K1312R | Missense Mutation (SNP) | VAF 54/206 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV52732631; called by muse, mutect2, varscan2
- LILRA2 | c.229G>T p.G77W | Missense Mutation (SNP) | VAF 305/636 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as COSV99253867; called by muse, mutect2, varscan2
- MEIOB | c.1221C>T p.F407= | Splice Region (SNP) | VAF 216/216 reads (100%) | catalogued as rs769160829; called by muse, mutect2, varscan2
- MIA2 | c.1342dup p.T448Nfs*5 | Frame Shift Ins (INS) | VAF 77/229 reads (34%) | catalogued as rs1362536399; called by mutect2, pindel, varscan2
- MROH9 | c.1373G>A p.C458Y | Missense Mutation (SNP) | VAF 124/464 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV63010840; called by muse, mutect2
- MRPS18A | c.239A>G p.K80R | Missense Mutation (SNP) | VAF 102/225 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs570316115; called by muse, mutect2, varscan2
- MYCBP2 | c.6920A>T p.D2307V (on ENST00000357337; = p.D2345V on NM_015057.5) | Missense Mutation (SNP) | VAF 48/1234 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV62014439; called by muse, mutect2
- MYO15A | c.9427A>T p.T3143S | Missense Mutation (SNP) | VAF 191/407 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as rs769625672; called by mutect2, varscan2
- MYO18A | c.170A>G p.K57R | Missense Mutation (SNP) | VAF 245/472 reads (52%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs1217116648; called by muse, mutect2, varscan2
- NARF | c.529C>T p.R177* | Nonsense Mutation (SNP) | VAF 129/241 reads (54%) | catalogued as rs770987175; called by muse, mutect2, varscan2
- NLRC3 | c.1093T>A p.S365T | Missense Mutation (SNP) | VAF 290/816 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0.166); catalogued as COSV57092052; called by muse, mutect2, varscan2
- NLRX1 | c.1750C>T p.R584* | Nonsense Mutation (SNP) | VAF 159/330 reads (48%) | catalogued as rs776884246, COSV52703995; called by muse, mutect2, varscan2
- NPAS2 | c.529T>G p.L177V | Missense Mutation (SNP) | VAF 67/542 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.074); catalogued as COSV59555677; called by muse, mutect2, varscan2
- NPAS3 | c.1799G>A p.R600H (on ENST00000356141 / NM_001164749.2; = p.R568H on NM_022123.3) | Missense Mutation (SNP) | VAF 273/538 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.749); catalogued as rs1421750160; called by muse, mutect2, varscan2
- NPR1 | c.1703G>A p.R568H | Missense Mutation (SNP) | VAF 115/480 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs750028514, COSV64117857; called by muse, mutect2, varscan2
- NUDT16 | c.22G>T p.E8* | Nonsense Mutation (SNP) | VAF 261/709 reads (37%) | catalogued as rs1282694328; called by muse, mutect2, varscan2
- NYNRIN | c.3828G>C p.Q1276H | Missense Mutation (SNP) | VAF 284/574 reads (49%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.936); catalogued as COSV101230572, COSV66842946; called by muse, mutect2, varscan2
- OR10C1 | c.683G>A p.R228Q (on ENST00000622521; = p.R226Q on NM_013941.3) | Missense Mutation (SNP) | VAF 948/948 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs139025176, COSV65822180; called by muse, mutect2, varscan2
- OR10J1 | c.260G>T p.G87V | Missense Mutation (SNP) | VAF 365/552 reads (66%) | SIFT tolerated (0.21); PolyPhen benign (0.033); catalogued as rs779297621; called by muse, mutect2, varscan2
- OR2T4 | c.504G>T p.M168I | Missense Mutation (SNP) | VAF 768/1376 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV63545190; called by muse, mutect2, varscan2
- OSBPL3 | c.108A>C p.E36D | Missense Mutation (SNP) | VAF 121/504 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57654265; called by muse, mutect2, varscan2
- OTOL1 | c.1223A>G p.Q408R | Missense Mutation (SNP) | VAF 207/645 reads (32%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV60006999; called by muse, mutect2, varscan2
- PAN2 | c.3419C>G p.A1140G (on ENST00000425394 / NM_001127460.3; = p.A1136G on NM_014871.5) | Missense Mutation (SNP) | VAF 188/358 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99228161; called by muse, mutect2, varscan2
- PCDH15 | c.4865G>A p.S1622N | Missense Mutation (SNP) | VAF 174/764 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.334); catalogued as COSV100214276, COSV57364058; called by muse, mutect2, varscan2
- PCDHA11 | c.2225G>A p.R742H | Missense Mutation (SNP) | VAF 448/449 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs374687707, COSV56514685; called by muse, mutect2, varscan2
- PDZD2 | c.2360G>A p.R787H | Missense Mutation (SNP) | VAF 304/447 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56853847; called by muse, mutect2, varscan2
- PGGT1B | c.1075C>G p.Q359E | Missense Mutation (SNP) | VAF 193/343 reads (56%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs1334625264; called by muse, mutect2, varscan2
- PINLYP | c.356T>G p.L119R | Missense Mutation (SNP) | VAF 158/285 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99746681; called by muse, mutect2, varscan2
- PLCD4 | c.1551C>G p.F517L | Missense Mutation (SNP) | VAF 182/377 reads (48%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as COSV68745333; called by muse, mutect2, varscan2
- PLD3 | c.283T>C p.F95L | Missense Mutation (SNP) | VAF 205/444 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.145); catalogued as rs1454071077; called by muse, mutect2, varscan2
- PRKD1 | c.1400C>T p.P467L | Missense Mutation (SNP) | VAF 76/159 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.35); catalogued as rs866059930; called by muse, mutect2, varscan2
- PRM3 | c.20A>C p.K7T | Missense Mutation (SNP) | VAF 225/658 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1458653426; called by muse, mutect2, varscan2
- PTGDS | c.427T>G p.F143V | Missense Mutation (SNP) | VAF 186/376 reads (49%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.946); catalogued as COSV56401743; called by muse, mutect2, varscan2
- PTPRC | c.1076T>G p.L359R | Missense Mutation (SNP) | VAF 59/242 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV61420536; called by muse, mutect2, varscan2
- RAD51 | c.79C>T p.R27W | Missense Mutation (SNP) | VAF 146/288 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs756713380, COSV104389575; called by muse, mutect2, varscan2
- RALGAPA2 | c.3797G>T p.W1266L | Missense Mutation (SNP) | VAF 248/521 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV52500798; called by muse, mutect2, varscan2
- RASGRP1 | c.937A>C p.S313R | Missense Mutation (SNP) | VAF 113/262 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.229); catalogued as COSV60363523; called by muse, mutect2, varscan2
- REG3A | c.373A>T p.S125C | Missense Mutation (SNP) | VAF 132/269 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.424); catalogued as COSV59409606; called by muse, mutect2, varscan2
- RFPL1 | c.181T>G p.F61V | Missense Mutation (SNP) | VAF 222/451 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.077); catalogued as COSV62978444; called by muse, mutect2, varscan2
- RHOD | c.177A>C p.Q59H | Missense Mutation (SNP) | VAF 86/562 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV58211052; called by muse, mutect2, varscan2
- RMC1 | c.1430A>T p.K477I | Missense Mutation (SNP) | VAF 146/1984 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV52571188; called by muse, mutect2
- RP1 | c.2153T>C p.L718P | Missense Mutation (SNP) | VAF 363/363 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1184356401; called by muse, mutect2, varscan2
- SALL1 | c.1966A>T p.T656S | Missense Mutation (SNP) | VAF 217/721 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV51759274; called by muse, mutect2, varscan2
- SEMA3A | c.2197C>T p.R733C | Missense Mutation (SNP) | VAF 139/627 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.613); catalogued as rs138002949; called by muse, mutect2, varscan2
- SEPTIN7 | c.306A>C p.E102D | Missense Mutation (SNP) | VAF 92/446 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.35); catalogued as COSV63255280; called by muse, mutect2, varscan2
- SHANK1 | c.6020C>T p.S2007L | Missense Mutation (SNP) | VAF 280/577 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as rs374977074; called by muse, mutect2, varscan2
- SMARCA4 | c.2573C>T p.T858M | Missense Mutation (SNP) | VAF 182/379 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1480398200, COSV60790124; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMG8 | c.1641C>A p.Y547* | Nonsense Mutation (SNP) | VAF 179/360 reads (50%) | catalogued as COSV56286553; called by muse, mutect2, varscan2
- SNRNP35 | c.443A>C p.K148T | Missense Mutation (SNP) | VAF 264/522 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63471739; called by muse, mutect2, varscan2
- SPATA48 | c.104T>C p.L35P | Missense Mutation (SNP) | VAF 143/630 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.925); catalogued as rs1467294464; called by muse, mutect2, varscan2
- SSH3 | c.758A>G p.E253G | Missense Mutation (SNP) | VAF 223/742 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as rs771481302; called by muse, mutect2, varscan2
- SYNRG | c.608A>C p.K203T | Missense Mutation (SNP) | VAF 99/245 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.403); catalogued as rs564423612; called by muse, mutect2, varscan2
- TACC2 | c.2615C>T p.S872F | Missense Mutation (SNP) | VAF 394/622 reads (63%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1270100081, COSV100553334, COSV57774728; called by muse, mutect2, varscan2
- THEG | c.815C>G p.S272* | Nonsense Mutation (SNP) | VAF 196/388 reads (51%) | catalogued as COSV100700632; called by muse, mutect2, varscan2
- TIMD4 | c.86C>T p.T29M | Missense Mutation (SNP) | VAF 288/596 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.084); catalogued as rs375659101; called by muse, mutect2, varscan2
- TMEM222 | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 278/453 reads (61%) | SIFT tolerated (0.27); PolyPhen benign (0.381); catalogued as rs148790942; called by muse, mutect2, varscan2
- TMEM79 | c.971G>A p.R324Q | Missense Mutation (SNP) | VAF 163/423 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs374556620; called by muse, mutect2, varscan2
- TNFAIP3 | c.404C>T p.T135I | Missense Mutation (SNP) | VAF 108/277 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.139); catalogued as COSV52803147; called by muse, mutect2, varscan2
- TNRC18 | c.3857A>G p.E1286G | Missense Mutation (SNP) | VAF 263/1101 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1344553673; called by muse, mutect2, varscan2
- TOGARAM2 | c.2581T>C p.S861P | Missense Mutation (SNP) | VAF 189/368 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1252448785; called by muse, mutect2, varscan2
- TP53 | c.8A>T p.E3V | Missense Mutation (SNP) | VAF 152/283 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV53377654; called by muse, varscan2
- TRIM3 | c.1706A>C p.K569T | Missense Mutation (SNP) | VAF 121/303 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.917); catalogued as COSV61983731; called by muse, mutect2, varscan2
- TSC2 | c.2639A>T p.K880M | Missense Mutation (SNP) | VAF 179/331 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CD991917; called by muse, mutect2, varscan2
- TTC16 | c.2401A>T p.S801C | Missense Mutation (SNP) | VAF 166/347 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV60161640; called by muse, mutect2, varscan2
- TTC6 | c.691G>T p.V231L | Missense Mutation (SNP) | VAF 267/528 reads (51%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV73288295; called by muse, mutect2, varscan2
- TXNDC11 | c.1474T>G p.F492V (on ENST00000356957 / NM_001303447.2; = p.F465V on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 201/598 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.04); catalogued as rs778444858; called by muse, mutect2, varscan2
- UBE2S | c.466G>A p.G156R | Missense Mutation (SNP) | VAF 279/558 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs1292690585; called by muse, mutect2, varscan2
- VARS2 | c.827T>C p.L276P | Missense Mutation (SNP) | VAF 216/636 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs908038990; called by muse, mutect2, varscan2
- VASH2 | c.970A>G p.R324G (on ENST00000517399 / NM_001301056.2; = p.R280G on NM_024749.5) | Missense Mutation (SNP) | VAF 105/350 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.295); catalogued as rs762040777; called by muse, mutect2, varscan2
- WRAP53 | c.962A>G p.K321R | Missense Mutation (SNP) | VAF 186/371 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as rs1299115479; called by muse, mutect2, varscan2
- WWC1 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 329/706 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54647410; called by muse, mutect2, varscan2
- XIRP2 | c.5204C>T p.T1735I (on ENST00000628543; = p.T1910I on NM_152381.6) | Missense Mutation (SNP) | VAF 173/437 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.942); catalogued as rs1414874983, COSV54735452; called by muse, mutect2, varscan2
- ZMAT3 | c.38A>G p.K13R | Missense Mutation (SNP) | VAF 123/388 reads (32%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs1370926880; called by muse, mutect2, varscan2
- ZMAT4 | c.86G>T p.R29L | Missense Mutation (SNP) | VAF 92/817 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1179422965, COSV52691419, COSV52703244; called by muse, mutect2, varscan2
- ZNF438 | c.428A>C p.K143T | Missense Mutation (SNP) | VAF 215/215 reads (100%) | SIFT tolerated (0.5); PolyPhen benign (0.034); catalogued as COSV59194229; called by muse, mutect2, varscan2
- ZNF514 | c.109T>G p.L37V | Missense Mutation (SNP) | VAF 136/545 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.816); catalogued as COSV54634242; called by muse, mutect2, varscan2
- ZNF764 | c.1183G>A p.V395M | Missense Mutation (SNP) | VAF 284/868 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1057275721, COSV53221004; called by muse, mutect2, varscan2
- ZNF770 | c.1067C>T p.S356F | Missense Mutation (SNP) | VAF 112/329 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.754); catalogued as rs1379039268, COSV62543886; called by muse, mutect2, varscan2
- ABCA2 | c.1724A>C p.N575T (on ENST00000614293; = p.N545T on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 270/574 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ABCA3 | c.2911T>C p.S971P | Missense Mutation (SNP) | VAF 254/493 reads (52%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- ABCC11 | c.3890A>G p.K1297R | Missense Mutation (SNP) | VAF 149/404 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- ABCG5 | c.819C>A p.F273L | Missense Mutation (SNP) | VAF 88/198 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- ABCG5 | c.818T>C p.F273S | Missense Mutation (SNP) | VAF 95/213 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ABI2 | c.433A>C p.I145L | Missense Mutation (SNP) | VAF 40/312 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- AC245033.1 | c.1391T>C p.V464A | Missense Mutation (SNP) | VAF 214/466 reads (46%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- ACACA | c.6400G>C p.D2134H | Missense Mutation (SNP) | VAF 280/565 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACSL6 | c.299T>G p.L100R (on ENST00000379240; = p.L125R on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 135/260 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ADAD2 | c.626A>G p.E209G (on ENST00000315906 / NM_001145400.2; = p.E281G on NM_139174.4) | Missense Mutation (SNP) | VAF 168/881 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAM15 | c.436A>G p.T146A | Missense Mutation (SNP) | VAF 137/456 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ADGRF5 | c.3815A>C p.K1272T | Missense Mutation (SNP) | VAF 120/247 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- AFAP1L1 | c.569A>G p.E190G | Missense Mutation (SNP) | VAF 111/548 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AFM | c.1033G>T p.A345S | Missense Mutation (SNP) | VAF 78/208 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0.018); called by muse, mutect2
- AHNAK | c.11879A>G p.D3960G | Missense Mutation (SNP) | VAF 183/381 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- AHNAK2 | c.13400A>C p.K4467T | Missense Mutation (SNP) | VAF 148/380 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKRD12 | c.2953A>G p.S985G | Missense Mutation (SNP) | VAF 85/261 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ANKRD28 | c.197G>C p.R66T | Missense Mutation (SNP) | VAF 119/237 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- APOB | c.13535A>C p.K4512T | Missense Mutation (SNP) | VAF 160/307 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- APOBEC3H | c.191A>C p.K64T | Missense Mutation (SNP) | VAF 164/536 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- ARHGAP35 | c.2300T>A p.L767Q | Missense Mutation (SNP) | VAF 153/311 reads (49%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.782); called by mutect2, varscan2
- ASB18 | c.982T>C p.S328P | Missense Mutation (SNP) | VAF 284/557 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- ASB6 | c.640T>G p.F214V | Missense Mutation (SNP) | VAF 211/421 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- ATG2B | c.5909A>C p.E1970A | Missense Mutation (SNP) | VAF 129/268 reads (48%) | SIFT tolerated (0.34); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- ATP10A | c.1330G>T p.V444L | Missense Mutation (SNP) | VAF 110/399 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- ATP6AP1 | c.632A>T p.K211M | Missense Mutation (SNP) | VAF 232/480 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- ATP8B2 | c.1615T>G p.F539V (on ENST00000672630; = p.F506V on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 250/659 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- AZIN1 | c.375A>C p.K125N | Missense Mutation (SNP) | VAF 149/301 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- BAIAP2L2 | c.931T>G p.S311A | Missense Mutation (SNP) | VAF 185/619 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- BSND | c.269A>C p.K90T | Missense Mutation (SNP) | VAF 140/439 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- C3orf33 | c.460T>G p.F154V (on ENST00000340171 / NM_001308229.2; = p.F111V on NM_173657.2) | Missense Mutation (SNP) | VAF 128/384 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- C9orf72 | c.4T>G p.S2A | Missense Mutation (SNP) | VAF 91/290 reads (31%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CAD | c.3149A>G p.K1050R | Missense Mutation (SNP) | VAF 183/387 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CAMSAP2 | c.3620A>C p.K1207T (on ENST00000236925 / NM_001297707.2; = p.K1196T on NM_203459.3) | Missense Mutation (SNP) | VAF 129/434 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- CARF | c.1896G>A p.M632I | Missense Mutation (SNP) | VAF 319/599 reads (53%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- CARMIL2 | c.3508A>T p.R1170* | Nonsense Mutation (SNP) | VAF 213/893 reads (24%) | called by muse, mutect2, varscan2
- CARNS1 | c.1505A>T p.K502M | Missense Mutation (SNP) | VAF 299/997 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC65 | c.461A>G p.E154G | Missense Mutation (SNP) | VAF 119/215 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- CCIN | c.1496A>G p.K499R | Missense Mutation (SNP) | VAF 205/629 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCL18 | c.26T>G p.L9R | Missense Mutation (SNP) | VAF 251/488 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- CD3G | c.280T>G p.S94A | Missense Mutation (SNP) | VAF 96/199 reads (48%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CDH3 | c.1573A>C p.S525R | Missense Mutation (SNP) | VAF 123/493 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- CDHR2 | c.2459A>C p.E820A | Missense Mutation (SNP) | VAF 264/1033 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CDIN1 | c.520C>A p.L174I (on ENST00000437989; = p.L76I on NM_032499.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 94/544 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- CDK9 | c.713T>C p.L238P | Missense Mutation (SNP) | VAF 252/510 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CELF1 | c.355T>A p.C119S | Missense Mutation (SNP) | VAF 151/459 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- CELSR2 | c.7025T>C p.V2342A | Missense Mutation (SNP) | VAF 178/374 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.306A>C p.Q102H | Missense Mutation (SNP) | VAF 133/392 reads (34%) | SIFT tolerated (0.67); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CGN | c.1091T>C p.L364P | Missense Mutation (SNP) | VAF 147/468 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CHD7 | c.6443T>A p.V2148D | Missense Mutation (SNP) | VAF 145/328 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CHKA | c.775G>T p.E259* | Nonsense Mutation (SNP) | VAF 46/318 reads (14%) | called by muse, varscan2
- CHL1 | c.656C>A p.P219Q | Missense Mutation (SNP) | VAF 113/223 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- CHRND | c.1522T>C p.S508P | Missense Mutation (SNP) | VAF 178/366 reads (49%) | SIFT tolerated (0.45); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- CIAPIN1 | c.740A>T p.K247M | Missense Mutation (SNP) | VAF 105/377 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- CIR1 | c.245A>C p.N82T | Missense Mutation (SNP) | VAF 71/278 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CKAP5 | c.4725A>C p.E1575D | Missense Mutation (SNP) | VAF 73/344 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CKAP5 | c.3644C>G p.S1215* | Nonsense Mutation (SNP) | VAF 127/331 reads (38%) | called by muse, mutect2, varscan2
- CLIC1 | c.305A>G p.E102G | Missense Mutation (SNP) | VAF 199/611 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CNTN2 | c.2543A>G p.E848G | Missense Mutation (SNP) | VAF 74/252 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- COG2 | c.136A>G p.R46G | Missense Mutation (SNP) | VAF 145/442 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- COG5 | c.143del p.T48Ifs*9 | Frame Shift Del (DEL) | VAF 189/396 reads (48%) | called by mutect2, pindel, varscan2
- COMMD7 | c.532A>C p.T178P | Missense Mutation (SNP) | VAF 123/563 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- CPA4 | c.75A>C p.Q25H | Missense Mutation (SNP) | VAF 111/231 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRLF1 | c.1190A>C p.K397T | Missense Mutation (SNP) | VAF 180/353 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by mutect2, varscan2
- CSMD3 | c.10043C>A p.T3348N (on ENST00000297405 / NM_001363185.1; = p.T3179N on NM_052900.3) | Missense Mutation (SNP) | VAF 136/253 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- CYP3A4 | c.425T>A p.L142H | Missense Mutation (SNP) | VAF 57/460 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CYP4X1 | c.605A>C p.N202T | Missense Mutation (SNP) | VAF 126/353 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- DAGLB | c.977T>C p.L326P | Missense Mutation (SNP) | VAF 119/568 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- DDB1 | c.950T>G p.L317R | Missense Mutation (SNP) | VAF 141/313 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DGLUCY | c.1753T>C p.S585P | Missense Mutation (SNP) | VAF 198/401 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- DLG4 | c.53A>G p.D18G (on ENST00000399506 / NM_001321075.3; = p.D61G on NM_001365.4) | Missense Mutation (SNP) | VAF 197/410 reads (48%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- DMRTA2 | c.1568A>G p.E523G | Missense Mutation (SNP) | VAF 231/746 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- DNAH11 | c.742A>T p.I248F | Missense Mutation (SNP) | VAF 362/751 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH11 | c.9923A>G p.E3308G | Missense Mutation (SNP) | VAF 95/388 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- DNAH12 | c.4177T>C p.S1393P (on ENST00000351747; = p.S1416P on NM_001366028.2) | Missense Mutation (SNP) | VAF 138/279 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH17 | c.11405A>G p.K3802R | Missense Mutation (SNP) | VAF 232/432 reads (54%) | SIFT tolerated (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DNAH7 | c.8494A>T p.R2832* | Nonsense Mutation (SNP) | VAF 261/681 reads (38%) | called by muse, mutect2, varscan2
- DNAH8 | c.5305T>C p.L1769= | Splice Region (SNP) | VAF 78/168 reads (46%) | called by muse, mutect2, varscan2
- DNAJC16 | c.730A>G p.S244G | Missense Mutation (SNP) | VAF 118/356 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, varscan2
- DPEP3 | c.521T>C p.L174P | Missense Mutation (SNP) | VAF 106/483 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DUOX1 | c.1919T>C p.L640P | Missense Mutation (SNP) | VAF 140/308 reads (45%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- EDEM2 | c.1687T>G p.F563V | Missense Mutation (SNP) | VAF 156/722 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- EIF2AK2 | c.988T>A p.F330I | Missense Mutation (SNP) | VAF 146/334 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- EIF2B4 | c.1397A>C p.K466T (on ENST00000347454 / NM_001034116.2; = p.K465T on NM_015636.3) | Missense Mutation (SNP) | VAF 149/328 reads (45%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EIF3B | c.1805T>G p.L602R | Missense Mutation (SNP) | VAF 98/409 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- ELL2 | c.1661A>C p.E554A | Missense Mutation (SNP) | VAF 142/306 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- EMC1 | c.2939A>C p.K980T | Missense Mutation (SNP) | VAF 148/449 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- EML5 | c.3778G>C p.D1260H | Missense Mutation (SNP) | VAF 175/372 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPHB2 | c.1999T>G p.F667V (on ENST00000400191 / NM_001309193.2; = p.F668V on NM_004442.7) | Missense Mutation (SNP) | VAF 193/571 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERC2 | c.2465G>C p.R822P | Missense Mutation (SNP) | VAF 197/408 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- ERCC8 | c.653G>T p.R218I | Missense Mutation (SNP) | VAF 212/456 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- ESD | c.830C>G p.A277G | Missense Mutation (SNP) | VAF 87/320 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ESPL1 | c.3034T>A p.L1012M | Missense Mutation (SNP) | VAF 140/330 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ETV5 | c.344A>G p.K115R | Missense Mutation (SNP) | VAF 64/228 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- F2 | c.1028A>G p.E343G | Missense Mutation (SNP) | VAF 146/351 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- FASN | c.5978A>G p.K1993R | Missense Mutation (SNP) | VAF 176/356 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- FASTKD2 | c.1430A>G p.Q477R | Missense Mutation (SNP) | VAF 83/176 reads (47%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBH1 | c.2794A>G p.T932A (on ENST00000362091 / NM_178150.3; = p.T983A on NM_032807.4) | Missense Mutation (SNP) | VAF 126/126 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- FBXL6 | c.1439T>G p.L480R | Missense Mutation (SNP) | VAF 162/517 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBXO7 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 96/213 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- FCRL1 | c.635T>C p.L212P | Missense Mutation (SNP) | VAF 126/364 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- FGL2 | c.1240A>C p.S414R | Missense Mutation (SNP) | VAF 191/831 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- FIGN | c.1611A>T p.R537S | Missense Mutation (SNP) | VAF 106/294 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- FN1 | c.2765A>C p.K922T | Missense Mutation (SNP) | VAF 240/475 reads (51%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FOXD3 | c.949G>A p.A317T | Missense Mutation (SNP) | VAF 459/697 reads (66%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- FRMPD3 | c.335T>C p.L112P | Missense Mutation (SNP) | VAF 176/358 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- FUZ | c.197A>G p.E66G | Missense Mutation (SNP) | VAF 162/344 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- GAK | c.1514T>C p.V505A | Missense Mutation (SNP) | VAF 110/247 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- GASK1A | c.217A>G p.R73G | Missense Mutation (SNP) | VAF 209/384 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GEN1 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.063); called by muse, varscan2
- GIPC3 | c.3440T>G p.L1147R | Missense Mutation (SNP) | VAF 167/327 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- GJA3 | c.1001A>G p.E334G | Missense Mutation (SNP) | VAF 326/1081 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- GLRA2 | c.614T>G p.L205* | Nonsense Mutation (SNP) | VAF 154/155 reads (99%) | called by muse, mutect2, varscan2
- GNAQ | c.458T>G p.L153* | Nonsense Mutation (SNP) | VAF 231/236 reads (98%) | called by muse, mutect2, varscan2
- GOLGA4 | c.2435A>G p.E812G | Missense Mutation (SNP) | VAF 114/234 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- GPR146 | c.134A>C p.N45T | Missense Mutation (SNP) | VAF 234/960 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR4 | c.1067A>C p.K356T | Missense Mutation (SNP) | VAF 219/438 reads (50%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRHL1 | c.1434C>A p.H478Q | Missense Mutation (SNP) | VAF 287/288 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GRM7 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 243/243 reads (100%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GTF3C1 | c.5446T>A p.S1816T | Missense Mutation (SNP) | VAF 284/766 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- HAS3 | c.680A>C p.E227A | Missense Mutation (SNP) | VAF 129/638 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- HDC | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 113/280 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HEATR5A | c.5768T>C p.L1923P | Missense Mutation (SNP) | VAF 169/333 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- HEMGN | c.815T>G p.L272R | Missense Mutation (SNP) | VAF 163/322 reads (51%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- HEMK1 | c.176A>T p.E59V | Missense Mutation (SNP) | VAF 171/308 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- HID1 | c.1159T>G p.F387V | Missense Mutation (SNP) | VAF 139/307 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- HIVEP2 | c.3565T>G p.L1189V | Missense Mutation (SNP) | VAF 131/271 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- HLX | c.904A>T p.T302S | Missense Mutation (SNP) | VAF 182/532 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- HMBS | c.82A>G p.S28G | Missense Mutation (SNP) | VAF 136/280 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- HMOX2 | c.590A>G p.Q197R | Missense Mutation (SNP) | VAF 251/803 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- HPCAL4 | c.527A>T p.K176M | Missense Mutation (SNP) | VAF 179/548 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- HSPA12B | c.175T>G p.F59V | Missense Mutation (SNP) | VAF 179/811 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- INPP5J | c.1972T>G p.F658V (on ENST00000331075 / NM_001284285.2; = p.F290V on NM_001002837.2) | Missense Mutation (SNP) | VAF 123/240 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- INSM1 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 237/978 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- INTS5 | c.1328T>A p.L443Q | Missense Mutation (SNP) | VAF 247/482 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ISLR | c.796C>T p.Q266* | Nonsense Mutation (SNP) | VAF 275/566 reads (49%) | called by muse, mutect2, varscan2
- ISX | c.231A>C p.E77D | Missense Mutation (SNP) | VAF 106/230 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- ITCH | c.2317T>G p.F773V (on ENST00000262650 / NM_001257137.3; = p.F732V on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/384 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ITGB2 | c.1908C>G p.C636W (on ENST00000302347; = p.C612W on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 353/568 reads (62%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ITLN2 | c.470A>C p.K157T | Missense Mutation (SNP) | VAF 153/458 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- ITPR3 | c.3947A>C p.K1316T | Missense Mutation (SNP) | VAF 125/380 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITPR3 | c.5888A>G p.E1963G | Missense Mutation (SNP) | VAF 158/506 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- ITPRIPL1 | c.722T>G p.I241S (on ENST00000439118 / NM_001008949.3; = p.I249S on NM_178495.6) | Missense Mutation (SNP) | VAF 246/924 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- JRK | c.926A>G p.E309G | Missense Mutation (SNP) | VAF 194/560 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- KALRN | c.911T>G p.L304R | Missense Mutation (SNP) | VAF 158/420 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KBTBD3 | c.842C>A p.S281Y | Missense Mutation (SNP) | VAF 175/351 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KDM7A | c.1154A>C p.E385A | Missense Mutation (SNP) | VAF 90/191 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIF20B | c.3763C>T p.Q1255* (on ENST00000371728 / NM_001284259.2; = p.Q1215* on NM_016195.4) | Nonsense Mutation (SNP) | VAF 30/106 reads (28%) | called by muse, varscan2
- KIF23 | c.2193G>C p.Q731H | Missense Mutation (SNP) | VAF 203/410 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- KLF18 | c.1274G>A p.G425D | Missense Mutation (SNP) | VAF 160/448 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KLHL15 | c.1507_1519del p.S503Rfs*31 | Frame Shift Del (DEL) | VAF 224/236 reads (95%) | called by mutect2, pindel, varscan2
- KRT17 | c.901T>G p.S301A | Missense Mutation (SNP) | VAF 145/329 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- KRT33B | c.929A>G p.Q310R | Missense Mutation (SNP) | VAF 258/611 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- KRT5 | c.350T>C p.L117P | Missense Mutation (SNP) | VAF 280/560 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- LFNG | c.983A>T p.E328V (on ENST00000222725 / NM_001040167.2; = p.E199V on NM_002304.2) | Missense Mutation (SNP) | VAF 130/590 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- LIN37 | c.617T>C p.L206P | Missense Mutation (SNP) | VAF 198/388 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- LIN7B | c.601T>C p.S201P | Missense Mutation (SNP) | VAF 163/314 reads (52%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- LMTK2 | c.1109T>G p.L370R | Missense Mutation (SNP) | VAF 166/1203 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- LRRC36 | c.1333A>C p.T445P | Missense Mutation (SNP) | VAF 156/587 reads (27%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- LRRC43 | c.1826A>C p.K609T | Missense Mutation (SNP) | VAF 160/332 reads (48%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- LYST | c.1853T>G p.L618R | Missense Mutation (SNP) | VAF 99/369 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- MAGEB6B | c.644C>A p.P215H | Missense Mutation (SNP) | VAF 180/180 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- MAP3K1 | c.4229T>A p.L1410Q | Missense Mutation (SNP) | VAF 115/509 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MARF1 | c.5056G>C p.D1686H | Missense Mutation (SNP) | VAF 387/659 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.336); called by muse, mutect2
- MARS1 | c.1091A>C p.K364T | Missense Mutation (SNP) | VAF 62/135 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MATN4 | c.1795A>G p.S599G (on ENST00000372754; = p.S558G on NM_003833.4) | Missense Mutation (SNP) | VAF 230/903 reads (25%) | PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MCM7 | c.1703A>G p.E568G | Missense Mutation (SNP) | VAF 140/1151 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- MED13L | c.4019A>C p.K1340T | Missense Mutation (SNP) | VAF 135/303 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- MKS1 | c.224A>G p.E75G | Missense Mutation (SNP) | VAF 145/282 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- MMP8 | c.414A>C p.E138D | Missense Mutation (SNP) | VAF 178/355 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MPL | c.1648A>C p.S550R | Missense Mutation (SNP) | VAF 279/451 reads (62%) | SIFT deleterious (0.02); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MROH2A | c.1730A>C p.K577T | Missense Mutation (SNP) | VAF 213/425 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- MS4A8 | c.403-1G>C p.X135_splice | Splice Site (SNP) | VAF 110/192 reads (57%) | called by muse, mutect2, varscan2
- MTCH2 | c.407T>G p.L136R | Missense Mutation (SNP) | VAF 135/352 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- MUC16 | c.24091A>G p.S8031G | Missense Mutation (SNP) | VAF 224/489 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- MUC22 | c.4537T>C p.S1513P | Missense Mutation (SNP) | VAF 198/662 reads (30%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.96); called by muse, varscan2
- MYCBP2 | c.3715A>T p.T1239S (on ENST00000357337; = p.T1277S on NM_015057.5) | Missense Mutation (SNP) | VAF 69/517 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- MYEOV | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 292/558 reads (52%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYH15 | c.2436A>C p.K812N | Missense Mutation (SNP) | VAF 134/411 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- MYH7B | c.4489T>G p.L1497V | Missense Mutation (SNP) | VAF 252/961 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- MYL9 | c.380T>C p.L127P | Missense Mutation (SNP) | VAF 126/564 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYO18B | c.2375A>C p.K792T | Missense Mutation (SNP) | VAF 104/483 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- NADK | c.419A>G p.K140R | Missense Mutation (SNP) | VAF 242/681 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NBEA | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 927/927 reads (100%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- NBPF10 | c.1818A>C p.Q606H | Missense Mutation (SNP) | VAF 59/392 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2
- NDC1 | c.938A>C p.E313A | Missense Mutation (SNP) | VAF 105/331 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- NECTIN1 | c.956C>T p.T319I | Missense Mutation (SNP) | VAF 166/342 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); called by muse, varscan2
- NEDD9 | c.2057A>G p.K686R | Missense Mutation (SNP) | VAF 126/393 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- NEFH | c.1652A>C p.K551T | Missense Mutation (SNP) | VAF 192/462 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.596); called by mutect2, varscan2
- NEK9 | c.602T>C p.L201P | Missense Mutation (SNP) | VAF 112/247 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NFS1 | c.520A>G p.T174A | Missense Mutation (SNP) | VAF 179/718 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- NINL | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 257/1024 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- NIPA1 | c.385A>C p.S129R | Missense Mutation (SNP) | VAF 166/522 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- NKTR | c.3541A>G p.S1181G | Missense Mutation (SNP) | VAF 168/348 reads (48%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRP1 | c.619C>A p.P207T | Missense Mutation (SNP) | VAF 257/258 reads (100%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- NOL9 | c.1449A>C p.E483D | Missense Mutation (SNP) | VAF 129/479 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- NPC1 | c.222T>G p.C74W | Missense Mutation (SNP) | VAF 169/1974 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NPR1 | c.2999A>C p.N1000T | Missense Mutation (SNP) | VAF 189/522 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- NR1H3 | c.640A>T p.I214F | Missense Mutation (SNP) | VAF 278/691 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- NSD1 | c.3031A>C p.S1011R | Missense Mutation (SNP) | VAF 154/683 reads (23%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NSD2 | c.2931A>C p.E977D | Missense Mutation (SNP) | VAF 153/342 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- NSD2 | c.3269A>C p.N1090T | Missense Mutation (SNP) | VAF 130/248 reads (52%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NUDC | c.890A>G p.K297R | Missense Mutation (SNP) | VAF 159/497 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- OBSCN | c.13822G>T p.V4608F | Missense Mutation (SNP) | VAF 191/582 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- OLFML2A | c.1853A>C p.N618T | Missense Mutation (SNP) | VAF 228/481 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- OR10V1 | c.919A>G p.R307G | Missense Mutation (SNP) | VAF 110/211 reads (52%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR1L1 | c.901T>G p.F301V (on ENST00000373686; = p.F251V on NM_001005236.3) | Missense Mutation (SNP) | VAF 190/415 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- OSTN | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 217/344 reads (63%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- OTOA | c.1633T>G p.S545A (on ENST00000286149; = p.S531A on NM_144672.4) | Missense Mutation (SNP) | VAF 123/405 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PAK1 | c.719A>T p.E240V | Missense Mutation (SNP) | VAF 165/320 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- PAPOLB | c.1337dup p.P447Afs*3 | Frame Shift Ins (INS) | VAF 144/734 reads (20%) | called by mutect2, pindel, varscan2
- PAXBP1 | c.2572C>T p.H858Y | Missense Mutation (SNP) | VAF 100/368 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- PC | c.3262T>A p.L1088M | Missense Mutation (SNP) | VAF 221/830 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PCDHGC5 | c.2450A>T p.E817V | Missense Mutation (SNP) | VAF 252/474 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by mutect2, varscan2
- PCNT | c.5811C>G p.H1937Q | Missense Mutation (SNP) | VAF 281/830 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PDCD11 | c.5136A>C p.E1712D | Missense Mutation (SNP) | VAF 106/222 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PDHX | c.656T>C p.L219P | Missense Mutation (SNP) | VAF 122/544 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- PDZD2 | c.6737C>A p.S2246Y | Missense Mutation (SNP) | VAF 234/740 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); called by muse, mutect2
- PEX11A | c.121G>T p.V41L | Missense Mutation (SNP) | VAF 162/285 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PEX16 | c.944T>A p.L315Q | Missense Mutation (SNP) | VAF 197/433 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- PIP5K1A | c.581A>T p.K194M (on ENST00000368888 / NM_001135638.2; = p.K181M on NM_003557.3) | Missense Mutation (SNP) | VAF 125/379 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLA2G6 | c.1559C>T p.T520I | Missense Mutation (SNP) | VAF 347/533 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- PLEKHG1 | c.2963A>C p.K988T | Missense Mutation (SNP) | VAF 194/366 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PLTP | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 187/939 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- PNPLA1 | c.1364T>C p.L455P (on ENST00000394571 / NM_001374623.1; = p.L360P on NM_173676.2) | Missense Mutation (SNP) | VAF 151/280 reads (54%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- PNPLA3 | c.524T>G p.F175C | Missense Mutation (SNP) | VAF 137/460 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- POGZ | c.3070A>G p.S1024G | Missense Mutation (SNP) | VAF 166/580 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- POLR3C | c.257T>C p.L86P | Missense Mutation (SNP) | VAF 185/565 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- PPFIA4 | c.3398G>A p.R1133H (on ENST00000447715; = p.R1134H on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 318/928 reads (34%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPL | c.637A>G p.S213G | Missense Mutation (SNP) | VAF 175/590 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PPP1R10 | c.1334A>G p.E445G | Missense Mutation (SNP) | VAF 184/609 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- PPP1R16B | c.1241A>C p.K414T | Missense Mutation (SNP) | VAF 171/702 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- PROX2 | c.405A>C p.Q135H | Missense Mutation (SNP) | VAF 216/448 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- PRR14 | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 365/569 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.569); called by muse, mutect2, varscan2
- PRSS1 | c.260T>A p.F87Y | Missense Mutation (SNP) | VAF 518/670 reads (77%) | SIFT tolerated (0.14); PolyPhen benign (0.096); called by muse, varscan2
- PTK2 | c.486A>C p.Q162H | Missense Mutation (SNP) | VAF 148/441 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- PTPRA | c.1603G>A p.E535K | Missense Mutation (SNP) | VAF 112/484 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PTS | c.182G>A p.G61E | Missense Mutation (SNP) | VAF 152/326 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- R3HDML | c.436T>A p.L146M | Missense Mutation (SNP) | VAF 192/803 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- RAB3A | c.38A>G p.E13G | Missense Mutation (SNP) | VAF 131/288 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RABL6 | c.1721A>T p.D574V | Missense Mutation (SNP) | VAF 199/410 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RASL12 | c.748A>G p.S250G | Missense Mutation (SNP) | VAF 201/452 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- RBM5 | c.287A>G p.E96G | Missense Mutation (SNP) | VAF 166/366 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- RELN | c.4145G>C p.S1382T | Missense Mutation (SNP) | VAF 228/335 reads (68%) | SIFT tolerated (0.2); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- RERE | c.27A>C p.K9N | Missense Mutation (SNP) | VAF 132/476 reads (28%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.261); called by muse, varscan2
- RESF1 | c.137A>C p.N46T | Missense Mutation (SNP) | VAF 156/350 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- RFX8 | c.308A>G p.K103R (on ENST00000646446; = p.K32R on NM_001145664.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 284/531 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- RGPD3 | c.4613A>C p.K1538T | Missense Mutation (SNP) | VAF 98/877 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RGPD8 | c.4610A>C p.K1537T | Missense Mutation (SNP) | VAF 32/348 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- RHBDL3 | c.655T>G p.F219V | Missense Mutation (SNP) | VAF 145/311 reads (47%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RIPOR1 | c.2744T>C p.L915P (on ENST00000379312 / NM_001193522.2; = p.L911P on NM_024519.4) | Missense Mutation (SNP) | VAF 177/833 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RLF | c.2858A>C p.K953T | Missense Mutation (SNP) | VAF 115/404 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- RMDN3 | c.767A>C p.K256T | Missense Mutation (SNP) | VAF 167/353 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); called by mutect2, varscan2
- RNF213 | c.10576G>T p.D3526Y | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); called by muse, mutect2
- RRAGC | c.255G>T p.M85I | Missense Mutation (SNP) | VAF 209/349 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- RYR3 | c.6070A>C p.I2024L | Missense Mutation (SNP) | VAF 180/547 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- SCAF1 | c.715T>C p.S239P | Missense Mutation (SNP) | VAF 102/240 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- SCT | c.137T>C p.L46P | Missense Mutation (SNP) | VAF 201/627 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SCUBE2 | c.1961A>T p.E654V | Missense Mutation (SNP) | VAF 85/391 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- SEMA3F | c.341A>C p.E114A | Missense Mutation (SNP) | VAF 157/295 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SENP3 | c.806T>G p.L269R | Missense Mutation (SNP) | VAF 180/381 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SEZ6L2 | c.1222T>C p.S408P (on ENST00000308713 / NM_001114099.3; = p.S338P on NM_012410.4) | Missense Mutation (SNP) | VAF 134/459 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- SH3TC2 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 391/791 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SHISA7 | c.1210C>T p.R404C | Missense Mutation (SNP) | VAF 288/626 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SIGIRR | c.349A>T p.S117C | Missense Mutation (SNP) | VAF 195/540 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- SKOR1 | c.2114C>T p.A705V | Missense Mutation (SNP) | VAF 308/668 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, varscan2
- SLC13A4 | c.509A>C p.N170T | Missense Mutation (SNP) | VAF 174/315 reads (55%) | SIFT tolerated (0.3); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- SLC22A18 | c.1091C>G p.T364S | Missense Mutation (SNP) | VAF 238/600 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- SLC25A18 | c.920G>C p.G307A | Missense Mutation (SNP) | VAF 130/411 reads (32%) | SIFT tolerated (0.65); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- SLC25A44 | c.835T>A p.S279T | Missense Mutation (SNP) | VAF 194/587 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- SLC26A4 | c.254T>G p.L85R | Missense Mutation (SNP) | VAF 178/571 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SLC27A4 | c.476A>C p.N159T | Missense Mutation (SNP) | VAF 308/605 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SLC35G1 | c.214T>G p.L72V (on ENST00000427197 / NM_001134658.3; = p.L71V on NM_153226.4) | Missense Mutation (SNP) | VAF 128/306 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- SLC40A1 | c.343T>G p.L115V | Missense Mutation (SNP) | VAF 175/746 reads (23%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- SLC4A2 | c.2452T>C p.F818L | Missense Mutation (SNP) | VAF 213/447 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- SLC6A18 | c.851A>C p.D284A | Missense Mutation (SNP) | VAF 130/516 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- SLC6A20 | c.862A>T p.I288L | Missense Mutation (SNP) | VAF 50/520 reads (10%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.447); called by muse, mutect2
- SNX17 | c.287A>G p.E96G | Missense Mutation (SNP) | VAF 140/271 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SNX9 | c.681A>C p.K227N | Missense Mutation (SNP) | VAF 98/187 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- SOGA1 | c.3050A>G p.E1017G | Missense Mutation (SNP) | VAF 163/779 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SOGA1 | c.2558A>T p.D853V | Missense Mutation (SNP) | VAF 119/523 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- SP110 | c.878A>C p.K293T | Missense Mutation (SNP) | VAF 90/220 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SPTY2D1OS | c.112A>G p.S38G | Missense Mutation (SNP) | VAF 112/455 reads (25%) | PolyPhen benign (0.302); called by muse, mutect2, varscan2
- SRA1 | c.548T>C p.L183P | Missense Mutation (SNP) | VAF 177/353 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SRCAP | c.5020A>G p.S1674G | Missense Mutation (SNP) | VAF 245/711 reads (34%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- SRRM2 | c.737A>G p.K246R | Missense Mutation (SNP) | VAF 114/251 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- STAU1 | c.68A>G p.K23R | Missense Mutation (SNP) | VAF 156/660 reads (24%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); called by muse, varscan2
- SYCP1 | c.1112C>A p.A371D | Missense Mutation (SNP) | VAF 226/226 reads (100%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- SYNE1 | c.18477G>C p.K6159N (on ENST00000367255 / NM_182961.4; = p.K6088N on NM_033071.3) | Missense Mutation (SNP) | VAF 224/419 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- SYNE3 | c.1716A>C p.Q572H | Missense Mutation (SNP) | VAF 259/501 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SYT12 | c.1010A>C p.K337T | Missense Mutation (SNP) | VAF 152/627 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYT5 | c.995A>G p.D332G | Missense Mutation (SNP) | VAF 286/572 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- TAF6 | c.1748A>C p.K583T | Missense Mutation (SNP) | VAF 259/2024 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- TAF6 | c.836T>C p.L279P | Missense Mutation (SNP) | VAF 134/1154 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TBATA | c.903A>C p.Q301H | Missense Mutation (SNP) | VAF 134/254 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TBATA | c.443A>C p.E148A | Missense Mutation (SNP) | VAF 135/314 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- TBC1D20 | c.646T>C p.F216L | Missense Mutation (SNP) | VAF 128/531 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- TBX20 | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 55/250 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- TBX21 | c.1436A>T p.E479V | Missense Mutation (SNP) | VAF 262/497 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- TCHHL1 | c.2360A>T p.E787V | Missense Mutation (SNP) | VAF 168/518 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- TCN2 | c.98A>C p.K33T | Missense Mutation (SNP) | VAF 167/337 reads (50%) | SIFT tolerated (0.58); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TCP11L1 | c.1472A>C p.K491T | Missense Mutation (SNP) | VAF 209/673 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- TECPR2 | c.2176A>G p.T726A | Missense Mutation (SNP) | VAF 206/425 reads (48%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TGS1 | c.845A>C p.K282T | Missense Mutation (SNP) | VAF 111/227 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TICRR | c.3149A>C p.K1050T | Missense Mutation (SNP) | VAF 112/229 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- TIMM17A | c.129A>T p.G43= | Splice Region (SNP) | VAF 108/348 reads (31%) | called by muse, mutect2, varscan2
- TLR5 | c.2135T>G p.L712R | Missense Mutation (SNP) | VAF 170/533 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TLR5 | c.569T>C p.L190P | Missense Mutation (SNP) | VAF 176/539 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMED6 | c.344_346del p.F115del | In Frame Del (DEL) | VAF 173/405 reads (43%) | called by mutect2, pindel, varscan2
- TMEM104 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 586/587 reads (100%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- TMEM151A | c.707T>C p.L236P | Missense Mutation (SNP) | VAF 375/377 reads (99%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMEM222 | c.9A>C p.E3D | Missense Mutation (SNP) | VAF 199/607 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TMEM271 | c.448G>T p.E150* | Nonsense Mutation (SNP) | VAF 186/409 reads (45%) | called by muse, mutect2, varscan2
- TMEM63A | c.485T>C p.L162P | Missense Mutation (SNP) | VAF 136/452 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- TNFSF13 | c.22T>G p.L8V | Missense Mutation (SNP) | VAF 180/345 reads (52%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- TNRC18 | c.8907A>G p.*2969Wext*136 | Nonstop Mutation (SNP) | VAF 138/523 reads (26%) | called by muse, mutect2, varscan2
- TNRC6C | c.536T>G p.L179R | Missense Mutation (SNP) | VAF 263/494 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TOP2A | c.1010T>G p.L337R | Missense Mutation (SNP) | VAF 151/319 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TPTE2 | c.185A>C p.K62T | Missense Mutation (SNP) | VAF 86/299 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TRAF3IP3 | c.1418A>C p.K473T | Missense Mutation (SNP) | VAF 128/359 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TRAF6 | c.1440A>C p.E480D | Missense Mutation (SNP) | VAF 108/489 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- TREML4 | c.190A>G p.T64A | Missense Mutation (SNP) | VAF 216/429 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- TRIM4 | c.521T>C p.V174A | Missense Mutation (SNP) | VAF 187/1316 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIM67 | c.1649A>G p.E550G | Missense Mutation (SNP) | VAF 170/540 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- TRIM72 | c.1031A>C p.E344A | Missense Mutation (SNP) | VAF 306/984 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TRPM1 | c.1964A>G p.E655G | Missense Mutation (SNP) | VAF 235/767 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRPM1 | c.1679A>C p.N560T | Missense Mutation (SNP) | VAF 163/538 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.155); called by mutect2, varscan2
- TSC2 | c.4547A>G p.K1516R | Missense Mutation (SNP) | VAF 170/345 reads (49%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- TSPAN33 | c.79T>G p.F27V | Missense Mutation (SNP) | VAF 179/379 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- TSPAN4 | c.322A>C p.T108P | Missense Mutation (SNP) | VAF 162/437 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.018); called by muse, varscan2
- TTC16 | c.1748A>G p.E583G | Missense Mutation (SNP) | VAF 142/275 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TTN | c.46905C>A p.Y15635* (on ENST00000591111; = p.Y8211* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 81/587 reads (14%) | called by muse, mutect2, varscan2
- TTYH2 | c.1189T>G p.F397V | Missense Mutation (SNP) | VAF 230/509 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TUFM | c.974T>C p.L325P | Missense Mutation (SNP) | VAF 210/643 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TXNDC11 | c.29G>A p.G10D | Missense Mutation (SNP) | VAF 270/936 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.143); called by mutect2, varscan2
- UBAP1 | c.635A>C p.E212A | Missense Mutation (SNP) | VAF 135/417 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- UBE3A | c.1652T>C p.L551S | Missense Mutation (SNP) | VAF 230/363 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UBOX5 | c.131A>G p.E44G | Missense Mutation (SNP) | VAF 153/555 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- UBQLN4 | c.731T>G p.L244R | Missense Mutation (SNP) | VAF 101/346 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- UGGT2 | c.1689A>C p.K563N | Missense Mutation (SNP) | VAF 74/173 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- UGT1A1 | c.87G>C p.K29N | Missense Mutation (SNP) | VAF 225/422 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- UNC45A | c.1469A>G p.E490G | Missense Mutation (SNP) | VAF 133/248 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- UTP14A | c.251A>C p.K84T | Missense Mutation (SNP) | VAF 165/340 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- UTP25 | c.1061A>C p.K354T | Missense Mutation (SNP) | VAF 102/326 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VSX1 | c.1098A>G p.*366Wext*33 | Nonstop Mutation (SNP) | VAF 130/522 reads (25%) | called by muse, mutect2, varscan2
- VWA7 | c.1378T>G p.L460V | Missense Mutation (SNP) | VAF 253/826 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- ZAN | c.1400T>C p.L467P | Missense Mutation (SNP) | VAF 289/1900 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- ZAN | c.4922T>A p.L1641H | Missense Mutation (SNP) | VAF 231/1448 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- ZAN | c.5908T>G p.F1970V | Missense Mutation (SNP) | VAF 211/1300 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- ZBBX | c.1196C>G p.T399S | Missense Mutation (SNP) | VAF 81/252 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- ZBED4 | c.262T>C p.S88P | Missense Mutation (SNP) | VAF 223/637 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- ZBED6 | c.377C>A p.P126H | Missense Mutation (SNP) | VAF 158/499 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZBTB38 | c.562A>G p.S188G | Missense Mutation (SNP) | VAF 135/513 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- ZC2HC1C | c.92A>G p.K31R | Missense Mutation (SNP) | VAF 200/443 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2
- ZCCHC12 | c.340T>G p.L114V | Missense Mutation (SNP) | VAF 148/353 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZDHHC1 | c.412T>G p.L138V | Missense Mutation (SNP) | VAF 142/595 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- ZDHHC18 | c.905T>A p.L302H | Missense Mutation (SNP) | VAF 117/417 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZKSCAN1 | c.850T>A p.S284T | Missense Mutation (SNP) | VAF 166/1184 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF213 | c.1194G>T p.E398D | Missense Mutation (SNP) | VAF 257/800 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ZNF226 | c.694G>C p.D232H | Missense Mutation (SNP) | VAF 24/294 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2
- ZNF281 | c.1582A>C p.S528R | Missense Mutation (SNP) | VAF 148/412 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- ZNF3 | c.1162A>G p.R388G | Missense Mutation (SNP) | VAF 213/1665 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- ZNF335 | c.3889T>C p.S1297P | Missense Mutation (SNP) | VAF 165/631 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF469 | c.6181A>G p.S2061G (on ENST00000437464; = p.S2089G on NM_001367624.2) | Missense Mutation (SNP) | VAF 313/1585 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ZNF592 | c.1715T>C p.L572P | Missense Mutation (SNP) | VAF 221/507 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF692 | c.444T>G p.C148W | Missense Mutation (SNP) | VAF 103/656 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF696 | c.461A>G p.E154G | Missense Mutation (SNP) | VAF 324/966 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- ZNF770 | c.1066T>C p.S356P | Missense Mutation (SNP) | VAF 113/329 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- ZNF8 | c.1445T>G p.L482R | Missense Mutation (SNP) | VAF 233/485 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF837 | c.956A>T p.K319M | Missense Mutation (SNP) | VAF 290/613 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- ZNF99 | c.2339A>C p.K780T | Missense Mutation (SNP) | VAF 152/303 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- ZSWIM8 | c.721A>G p.S241G | Missense Mutation (SNP) | VAF 134/534 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- ADAD1 | c.585A>G p.S195= | Silent (SNP) | VAF 203/203 reads (100%) | called by muse, mutect2, varscan2
- ADAM23 | c.294C>T p.S98= | Silent (SNP) | VAF 109/267 reads (41%) | catalogued as rs1372175363; called by muse, mutect2, varscan2
- ADAMTS1 | c.15G>A p.V5= | Silent (SNP) | VAF 187/554 reads (34%) | called by muse, mutect2, varscan2
- ADAMTS2 | c.396G>A p.A132= | Silent (SNP) | VAF 320/1404 reads (23%) | catalogued as rs770621969; called by muse, mutect2, varscan2
- ALKBH3 | c.391A>C p.R131= | Silent (SNP) | VAF 109/310 reads (35%) | called by muse, mutect2, varscan2
- ARHGEF37 | c.297A>G p.Q99= | Silent (SNP) | VAF 73/366 reads (20%) | called by muse, mutect2, varscan2
- ART1 | c.801A>G p.R267= | Silent (SNP) | VAF 150/421 reads (36%) | called by muse, mutect2, varscan2
- AUP1 | c.1152G>A p.E384= | Silent (SNP) | VAF 16/324 reads (5%) | called by muse, mutect2
- BAHCC1 | c.1419C>T p.S473= | Silent (SNP) | VAF 626/628 reads (100%) | catalogued as rs1165340093, COSV100311579; called by muse, mutect2, varscan2
- BBS5 | c.244A>C p.R82= | Silent (SNP) | VAF 93/374 reads (25%) | called by muse, mutect2, varscan2
- BCAN | c.825G>A p.A275= | Silent (SNP) | VAF 180/558 reads (32%) | catalogued as rs776798315, COSV61255405; called by muse, mutect2, varscan2
- BICRA | c.1875C>G p.P625= | Silent (SNP) | VAF 300/581 reads (52%) | called by muse, mutect2, varscan2
- BRCA2 | c.9597T>C p.T3199= | Silent (SNP) | VAF 160/553 reads (29%) | catalogued as rs1057522578; ClinVar: likely benign; called by muse, mutect2, varscan2
- C4BPA | c.648T>C p.S216= | Silent (SNP) | VAF 153/312 reads (49%) | called by muse, mutect2, varscan2
- CAMSAP2 | c.333T>G p.G111= | Silent (SNP) | VAF 172/541 reads (32%) | catalogued as rs1312112954; called by muse, mutect2, varscan2
- CAPRIN2 | c.1341A>C p.S447= | Silent (SNP) | VAF 288/288 reads (100%) | called by muse, mutect2, varscan2
- CC2D2B | c.327T>G p.S109= (on ENST00000646931 / NM_001349008.3; = p.S101= on NM_001130446.3) | Silent (SNP) | VAF 134/320 reads (42%) | called by muse, mutect2, varscan2
- CCNJ | c.252A>G p.L84= | Silent (SNP) | VAF 139/277 reads (50%) | called by muse, mutect2, varscan2
- CDH13 | c.2061G>C p.V687= | Silent (SNP) | VAF 217/991 reads (22%) | called by muse, mutect2, varscan2
- CKAP5 | c.3849T>C p.T1283= | Silent (SNP) | VAF 117/339 reads (35%) | catalogued as rs1265225562; called by muse, mutect2, varscan2
- CLK1 | c.312T>G p.S104= | Silent (SNP) | VAF 219/660 reads (33%) | catalogued as rs1259152216; called by muse, mutect2, varscan2
- COL12A1 | c.1827T>G p.S609= | Silent (SNP) | VAF 173/370 reads (47%) | catalogued as rs563760017; called by muse, mutect2, varscan2
- COQ7 | c.267A>G p.Q89= | Silent (SNP) | VAF 118/375 reads (31%) | called by muse, mutect2, varscan2
- CRHR2 | c.177C>T p.L59= | Silent (SNP) | VAF 279/596 reads (47%) | catalogued as COSV100530191; called by muse, mutect2, varscan2
- CROCC | c.2127G>A p.A709= | Silent (SNP) | VAF 93/311 reads (30%) | catalogued as rs778904057; called by muse, mutect2, varscan2
- DCTN1 | c.3645T>C p.P1215= | Silent (SNP) | VAF 101/211 reads (48%) | catalogued as rs1442543560; called by muse, mutect2, varscan2
- DGCR8 | c.945A>T p.G315= | Silent (SNP) | VAF 185/620 reads (30%) | called by muse, mutect2, varscan2
- DHFR2 | c.465G>A p.E155= | Silent (SNP) | VAF 35/652 reads (5%) | catalogued as COSV58935978; called by muse, mutect2
- DHX16 | c.1573A>C p.R525= | Silent (SNP) | VAF 223/724 reads (31%) | called by muse, mutect2, varscan2
- DYNC2I2 | c.1356A>T p.A452= | Silent (SNP) | VAF 159/320 reads (50%) | called by muse, mutect2, varscan2
- ESR1 | c.180C>T p.Y60= | Silent (SNP) | VAF 703/706 reads (100%) | catalogued as rs750785561, COSV52796255; called by muse, mutect2, varscan2
- FLG | c.4062A>G p.G1354= | Silent (SNP) | VAF 195/700 reads (28%) | called by muse, mutect2, varscan2
- FSIP2 | c.19737C>T p.Y6579= | Silent (SNP) | VAF 88/581 reads (15%) | called by muse, mutect2, varscan2
- GABRB3 | c.1278C>A p.T426= | Silent (SNP) | VAF 177/540 reads (33%) | called by muse, mutect2, varscan2
- GAL3ST3 | c.297G>A p.P99= | Silent (SNP) | VAF 351/352 reads (100%) | catalogued as rs757341959, COSV61748736; called by muse, varscan2
- GALNT2 | c.808T>C p.L270= | Silent (SNP) | VAF 134/403 reads (33%) | called by muse, mutect2, varscan2
- HEATR5A | c.6000T>G p.A2000= | Silent (SNP) | VAF 142/315 reads (45%) | called by muse, mutect2, varscan2
- HECTD1 | c.516A>G p.R172= | Silent (SNP) | VAF 161/345 reads (47%) | called by muse, mutect2, varscan2
- HECW1 | c.1632G>A p.T544= | Silent (SNP) | VAF 423/826 reads (51%) | catalogued as rs768142577, COSV101224174, COSV67830395; called by muse, mutect2, varscan2
- HSPB1 | c.333C>G p.V111= | Silent (SNP) | VAF 192/797 reads (24%) | called by muse, mutect2, varscan2
- IKBKE | c.1068T>A p.G356= | Silent (SNP) | VAF 227/758 reads (30%) | called by muse, mutect2, varscan2
- IL18R1 | c.1599A>G p.E533= | Silent (SNP) | VAF 138/513 reads (27%) | called by muse, mutect2, varscan2
- INO80B | c.339A>G p.G113= | Silent (SNP) | VAF 122/276 reads (44%) | called by muse, mutect2, varscan2
- INPP5J | c.846A>T p.R282= | Silent (SNP) | VAF 344/711 reads (48%) | called by muse, mutect2, varscan2
- ITPR1 | c.3888C>T p.F1296= (on ENST00000354582; = p.F1281= on NM_002222.7) | Silent (SNP) | VAF 171/400 reads (43%) | catalogued as rs923372943, COSV57003283; called by muse, mutect2, varscan2
- ITPR3 | c.5148A>G p.P1716= | Silent (SNP) | VAF 205/599 reads (34%) | called by muse, mutect2, varscan2
- KANK4 | c.178A>C p.R60= | Silent (SNP) | VAF 166/495 reads (34%) | called by mutect2, varscan2
- KBTBD7 | c.1344A>G p.G448= | Silent (SNP) | VAF 161/554 reads (29%) | called by muse, mutect2, varscan2
- KCNMB2 | c.213C>T p.R71= | Silent (SNP) | VAF 125/330 reads (38%) | catalogued as rs767083573; called by muse, mutect2, varscan2
- KIN | c.1024A>C p.R342= | Silent (SNP) | VAF 74/74 reads (100%) | called by muse, varscan2
- L3MBTL2 | c.1377G>A p.L459= | Silent (SNP) | VAF 124/412 reads (30%) | called by muse, mutect2, varscan2
- LIMS2 | c.741T>A p.T247= (on ENST00000355119 / NM_001161403.3; = p.T271= on NM_017980.4) | Silent (SNP) | VAF 150/589 reads (25%) | called by muse, mutect2, varscan2
- LMTK2 | c.457T>C p.L153= | Silent (SNP) | VAF 106/836 reads (13%) | called by muse, mutect2
- LOXL2 | c.243C>T p.G81= | Silent (SNP) | VAF 197/197 reads (100%) | catalogued as rs1436553225; called by muse, mutect2, varscan2
- LSM2 | c.195A>C p.S65= | Silent (SNP) | VAF 189/622 reads (30%) | catalogued as rs1394128865; called by muse, mutect2, varscan2
- LY6K | c.495T>G p.S165= | Silent (SNP) | VAF 147/395 reads (37%) | called by muse, mutect2, varscan2
- MAGEA1 | c.57A>G p.Q19= | Silent (SNP) | VAF 414/415 reads (100%) | called by muse, mutect2, varscan2
- MED8 | c.136C>T p.L46= | Silent (SNP) | VAF 110/394 reads (28%) | called by muse, mutect2, varscan2
- MEGF11 | c.1257T>C p.T419= | Silent (SNP) | VAF 268/558 reads (48%) | called by muse, mutect2, varscan2
- MSLN | c.888A>G p.E296= | Silent (SNP) | VAF 190/385 reads (49%) | called by muse, mutect2, varscan2
- MUC17 | c.4290T>A p.S1430= | Silent (SNP) | VAF 187/1184 reads (16%) | called by muse, mutect2, varscan2
- MUC22 | c.2580T>C p.T860= | Silent (SNP) | VAF 316/1055 reads (30%) | called by muse, mutect2, varscan2
- MUC22 | c.2997T>G p.T999= | Silent (SNP) | VAF 263/890 reads (30%) | called by muse, mutect2, varscan2
- MUC22 | c.4350T>C p.T1450= | Silent (SNP) | VAF 320/926 reads (35%) | catalogued as rs1328047072; called by muse, varscan2
- MYO18A | c.2964C>T p.I988= | Silent (SNP) | VAF 502/502 reads (100%) | catalogued as rs1399791273; called by muse, mutect2, varscan2
- NCKAP1 | c.444T>C p.S148= | Silent (SNP) | VAF 96/392 reads (24%) | catalogued as COSV100720609; called by muse, mutect2, varscan2
- NOL12 | c.205T>C p.L69= | Silent (SNP) | VAF 210/589 reads (36%) | called by muse, mutect2, varscan2
- NT5DC4 | c.571T>C p.L191= | Silent (SNP) | VAF 184/677 reads (27%) | catalogued as rs779791643; called by muse, mutect2, varscan2
- NYAP1 | c.102T>A p.A34= | Silent (SNP) | VAF 230/1776 reads (13%) | called by muse, mutect2, varscan2
- OPN5 | c.375T>C p.T125= | Silent (SNP) | VAF 155/344 reads (45%) | called by muse, mutect2, varscan2
- OPRK1 | c.939C>T p.Y313= | Silent (SNP) | VAF 192/406 reads (47%) | catalogued as rs776486303; called by muse, mutect2, varscan2
- OR4D6 | c.300G>A p.Q100= | Silent (SNP) | VAF 196/409 reads (48%) | catalogued as rs1485875312; called by muse, mutect2, varscan2
- OR56B1 | c.579C>T p.V193= | Silent (SNP) | VAF 129/505 reads (26%) | catalogued as rs979529745; called by muse, mutect2, varscan2
- PAPPA | c.846T>A p.P282= | Silent (SNP) | VAF 210/471 reads (45%) | called by muse, mutect2, varscan2
- PARP15 | c.594T>G p.S198= | Silent (SNP) | VAF 148/466 reads (32%) | called by muse, mutect2, varscan2
- PCDH15 | c.5511C>A p.S1837= | Silent (SNP) | VAF 39/852 reads (5%) | called by muse, mutect2
- PCDHA9 | c.1854G>A p.A618= | Silent (SNP) | VAF 237/420 reads (56%) | catalogued as rs1554144220, COSV65325301; called by muse, mutect2, varscan2
- PDE8B | c.1788T>C p.T596= | Silent (SNP) | VAF 200/376 reads (53%) | called by muse, mutect2, varscan2
- PI4KB | c.579C>T p.A193= (on ENST00000368873 / NM_001369623.1; = p.A205= on NM_002651.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 260/728 reads (36%) | called by muse, mutect2, varscan2
- PLEC | c.6798T>A p.A2266= (on ENST00000322810 / NM_201380.4; = p.A2156= on NM_000445.5) | Silent (SNP) | VAF 353/1071 reads (33%) | called by muse, mutect2, varscan2
- PLEKHA4 | c.1011G>A p.P337= | Silent (SNP) | VAF 210/417 reads (50%) | catalogued as rs774684610, COSV54361251; called by muse, mutect2, varscan2
- PLK1 | c.270C>G p.L90= | Silent (SNP) | VAF 192/626 reads (31%) | catalogued as COSV55622964; called by muse, mutect2, varscan2
- PPM1A | c.534A>G p.A178= | Silent (SNP) | VAF 127/244 reads (52%) | catalogued as rs1165085620; called by muse, mutect2, varscan2
- PRODH | c.1695C>G p.A565= | Silent (SNP) | VAF 435/455 reads (96%) | called by muse, mutect2, varscan2
- PRRT3 | c.597T>G p.T199= | Silent (SNP) | VAF 208/437 reads (48%) | called by muse, mutect2, varscan2
- PRUNE2 | c.1869T>G p.T623= | Silent (SNP) | VAF 178/364 reads (49%) | called by muse, mutect2, varscan2
- RANBP2 | c.7617A>G p.S2539= | Silent (SNP) | VAF 159/631 reads (25%) | called by muse, mutect2, varscan2
- RBMXL3 | c.1281A>C p.R427= | Silent (SNP) | VAF 267/605 reads (44%) | called by muse, mutect2, varscan2
- RIOK3 | c.1419C>T p.I473= | Silent (SNP) | VAF 104/1494 reads (7%) | catalogued as rs569930927; called by muse, mutect2
- RNF10 | c.594T>A p.A198= | Silent (SNP) | VAF 99/237 reads (42%) | called by muse, mutect2, varscan2
- RNF123 | c.2040A>G p.R680= | Silent (SNP) | VAF 234/552 reads (42%) | catalogued as rs747577471, COSV59686645; called by muse, mutect2, varscan2
- RNMT | c.990T>G p.A330= | Silent (SNP) | VAF 50/200 reads (25%) | called by muse, mutect2, varscan2
- RTN4IP1 | c.733A>C p.R245= | Silent (SNP) | VAF 200/412 reads (49%) | called by muse, mutect2, varscan2
- SCAP | c.1545G>A p.L515= | Silent (SNP) | VAF 162/335 reads (48%) | called by muse, mutect2, varscan2
- SEMA6B | c.2139G>A p.T713= | Silent (SNP) | VAF 392/827 reads (47%) | catalogued as rs1259903046; called by muse, mutect2, varscan2
- SF3B3 | c.597A>G p.E199= | Silent (SNP) | VAF 223/639 reads (35%) | catalogued as COSV56787876; called by muse, mutect2, varscan2
- SHLD1 | c.478T>C p.L160= | Silent (SNP) | VAF 208/847 reads (25%) | called by muse, mutect2, varscan2
- SLC25A25 | c.441C>T p.P147= | Silent (SNP) | VAF 156/333 reads (47%) | catalogued as rs576891746, COSV100895316; called by muse, mutect2, varscan2
- SLC41A3 | c.108A>G p.E36= | Silent (SNP) | VAF 234/765 reads (31%) | called by muse, mutect2, varscan2
- SMG1 | c.159T>G p.S53= | Silent (SNP) | VAF 137/451 reads (30%) | called by muse, mutect2, varscan2
- SNRNP200 | c.3000T>C p.T1000= | Silent (SNP) | VAF 137/599 reads (23%) | called by muse, mutect2, varscan2
- SPINK5 | c.3000C>A p.P1000= | Silent (SNP) | VAF 264/556 reads (47%) | called by muse, mutect2
- SRP68 | c.796A>C p.R266= | Silent (SNP) | VAF 137/259 reads (53%) | called by muse, mutect2, varscan2
- SRRM2 | c.5058T>C p.P1686= | Silent (SNP) | VAF 201/396 reads (51%) | catalogued as rs1211302654; called by muse, mutect2, varscan2
- STARD9 | c.1959G>A p.Q653= | Silent (SNP) | VAF 141/338 reads (42%) | catalogued as rs764060117, COSV51903299; called by muse, mutect2, varscan2
- SYT15 | c.252A>G p.Q84= | Silent (SNP) | VAF 105/284 reads (37%) | called by muse, mutect2, varscan2
- TACR1 | c.345T>C p.A115= | Silent (SNP) | VAF 166/328 reads (51%) | called by muse, mutect2, varscan2
- TAF5L | c.951T>A p.A317= | Silent (SNP) | VAF 78/301 reads (26%) | called by muse, mutect2, varscan2
- TCEA2 | c.732A>G p.R244= | Silent (SNP) | VAF 230/933 reads (25%) | catalogued as rs1316139615; called by muse, mutect2, varscan2
- TCHH | c.5115A>G p.R1705= | Silent (SNP) | VAF 163/466 reads (35%) | called by muse, mutect2, varscan2
- TEKT3 | c.993G>A p.V331= | Silent (SNP) | VAF 364/364 reads (100%) | called by muse, mutect2, varscan2
- TEKT4 | c.1137G>T p.L379= | Silent (SNP) | VAF 259/620 reads (42%) | called by muse, mutect2, varscan2
- TESK2 | c.1170A>T p.R390= | Silent (SNP) | VAF 195/611 reads (32%) | called by muse, mutect2, varscan2
- TLE7 | c.1200T>G p.P400= | Silent (SNP) | VAF 90/517 reads (17%) | called by muse, mutect2, varscan2
- TRRAP | c.3417T>C p.S1139= | Silent (SNP) | VAF 124/999 reads (12%) | called by muse, mutect2, varscan2
- TTC25 | c.1875A>T p.G625= | Silent (SNP) | VAF 179/369 reads (49%) | catalogued as COSV101102942; called by muse, mutect2, varscan2
- TTC3 | c.3264T>C p.S1088= | Silent (SNP) | VAF 143/457 reads (31%) | called by muse, mutect2, varscan2
- TTC8 | c.1239T>G p.A413= (on ENST00000338104 / NM_001288781.1; = p.A397= on NM_144596.4) | Silent (SNP) | VAF 119/254 reads (47%) | called by muse, mutect2, varscan2
- UGT2B17 | c.1362G>A p.P454= | Silent (SNP) | VAF 333/333 reads (100%) | catalogued as rs746870450; called by muse, mutect2, varscan2
- VCL | c.1059T>C p.A353= | Silent (SNP) | VAF 187/642 reads (29%) | catalogued as COSV53008236; called by muse, mutect2, varscan2
- VPS54 | c.2478T>C p.A826= | Silent (SNP) | VAF 134/272 reads (49%) | called by muse, mutect2, varscan2
- WT1 | c.198G>A p.A66= | Silent (SNP) | VAF 931/1896 reads (49%) | catalogued as COSV60072422; called by muse, mutect2, varscan2
- ZAN | c.1467T>G p.P489= | Silent (SNP) | VAF 240/1686 reads (14%) | called by muse, varscan2
- ZMIZ2 | c.2557T>C p.L853= | Silent (SNP) | VAF 274/1230 reads (22%) | catalogued as COSV99537363; called by muse, mutect2, varscan2
- ZNF280A | c.204A>T p.P68= | Silent (SNP) | VAF 511/766 reads (67%) | called by muse, mutect2, varscan2
- ZNF318 | c.6016T>C p.L2006= | Silent (SNP) | VAF 177/366 reads (48%) | called by muse, mutect2, varscan2
- ZNF579 | c.1677C>T p.G559= | Silent (SNP) | VAF 151/314 reads (48%) | called by muse, mutect2, varscan2
- ZNF778 | c.1974T>C p.S658= | Silent (SNP) | VAF 166/774 reads (21%) | called by muse, mutect2, varscan2
- ZNF784 | c.339C>A p.P113= | Silent (SNP) | VAF 350/704 reads (50%) | catalogued as COSV57596374; called by muse, mutect2, varscan2
- ZSCAN30 | c.426A>G p.Q142= | Silent (SNP) | VAF 223/223 reads (100%) | called by muse, mutect2, varscan2
- CD300LG | c.379+13T>C | Intron (SNP) | VAF 216/424 reads (51%) | called by muse, mutect2, varscan2
- GNAO1 | c.161+20696A>T | Intron (SNP) | VAF 338/522 reads (65%) | called by muse, mutect2, varscan2
- IGFN1 | c.1241+3454T>G | Intron (SNP) | VAF 166/739 reads (22%) | called by mutect2, varscan2
- KCNQ1 | c.1393+23844T>G | Intron (SNP) | VAF 135/350 reads (39%) | called by muse, mutect2, varscan2
- LMO7 | c.3338-27T>C | Intron (SNP) | VAF 169/945 reads (18%) | called by muse, mutect2, varscan2
- MARVELD3 | chr16:71640985 T>G | 3'Flank (SNP) | VAF 151/811 reads (19%) | called by muse, mutect2, varscan2
- NOTCH1 | c.*601A>T | 3'UTR (SNP) | VAF 201/396 reads (51%) | called by muse, mutect2, varscan2
- NPAP1L | n.307C>A | RNA (SNP) | VAF 103/352 reads (29%) | called by muse, varscan2
- OR5R1 | chr11:56413392 T>C | 3'Flank (SNP) | VAF 159/329 reads (48%) | called by muse, mutect2, varscan2
- PKMYT1 | chr16:2972709 A>G | 3'Flank (SNP) | VAF 184/588 reads (31%) | called by muse, mutect2, varscan2
- RMDN2 | c.453-21843A>G | Intron (SNP) | VAF 189/359 reads (53%) | catalogued as rs763347521; called by muse, mutect2, varscan2
- SLC35A5 | c.*299T>G | 3'UTR (SNP) | VAF 129/450 reads (29%) | called by muse, mutect2, varscan2
- SPEF2 | c.4448-3726G>T | Intron (SNP) | VAF 107/400 reads (27%) | catalogued as COSV57432922; called by muse, mutect2, varscan2
- TAL1 | c.*2161T>G | 3'UTR (SNP) | VAF 149/530 reads (28%) | called by muse, mutect2, varscan2
- TRPM2 | c.3462-1372A>G | Intron (SNP) | VAF 128/370 reads (35%) | called by muse, mutect2, varscan2
- TTN | c.10361-4451T>G | Intron (SNP) | VAF 209/537 reads (39%) | called by muse, mutect2, varscan2
- TTN | c.10360+4769T>C | Intron (SNP) | VAF 80/483 reads (17%) | catalogued as rs767802140; called by muse, mutect2, varscan2
- USH1C | c.1284+6973T>C | Intron (SNP) | VAF 126/335 reads (38%) | called by muse, mutect2, varscan2
- VSX1 | c.*1G>A | 3'UTR (SNP) | VAF 129/517 reads (25%) | called by muse, mutect2, varscan2
- WDR59 | c.1389+25T>C | Intron (SNP) | VAF 372/1009 reads (37%) | called by muse, mutect2, varscan2
- WFDC21P | n.417A>C | RNA (SNP) | VAF 174/370 reads (47%) | called by muse, mutect2, varscan2
- Z99774.2 | chr22:26669539 T>G | 5'Flank (SNP) | VAF 158/611 reads (26%) | called by muse, mutect2, varscan2
- Z99774.2 | chr22:26669886 A>C | 5'Flank (SNP) | VAF 161/706 reads (23%) | called by muse, mutect2, varscan2
- Z99774.4 | chr22:26666593 A>C | 5'Flank (SNP) | VAF 172/755 reads (23%) | called by muse, mutect2, varscan2
